CCDI case PBCMYB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/ecdb7f19-5031-44c1-8269-3cfccc06745f

Demographics
Sex at birth: female; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Tumor cells, uncertain whether benign or malignant: ICD-O-3 morphology code: 8001/1; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 9.5 years (3,479 days).

Biospecimens (3 samples)
- Sample 0DVJNW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVJO8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVJOM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
